FM case AD18004 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/a6dfd56c-787f-4d69-be43-9816be7e4919

Female, 25.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the overlapping lesion of nasopharynx; metastasis. Sample type: Metastatic.
